Somatic mutation profile of tumor specimen TCGA-13-1482-01A (aliquot TCGA-13-1482-01A-01W-0549-09) from TCGA case TCGA-13-1482, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 52.5 years (19,178 days).
Specimen TCGA-13-1482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 355ddd23-8896-4d66-9e7e-7b57c816e0ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1482-10A (Blood Derived Normal), aliquot TCGA-13-1482-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/472ac858-65b5-4b38-b4a6-7acb52b3cd89

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Splice Site 6, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 53/74 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.570-1G>T p.X190_splice | Splice Site (SNP) | VAF 36/81 reads (44%) | catalogued as COSV53050509; called by muse, mutect2, varscan2
- ADGRB3 | c.3036-2A>T p.X1012_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as COSV53262873; called by muse, mutect2, varscan2
- AK2 | c.585G>C p.M195I (on ENST00000354858; = p.M237I on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/128 reads (67%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV61470527; called by muse, varscan2
- BBS12 | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV58563258; called by muse, mutect2, varscan2
- BICC1 | c.1921G>T p.G641C | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as COSV99570385; called by muse, mutect2, varscan2
- BICC1 | c.1922G>T p.G641V | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV99570387; called by muse, mutect2, varscan2
- CLCA2 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 141/403 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV65289075; called by muse, mutect2, varscan2
- CNTNAP5 | c.3789C>A p.Y1263* | Nonsense Mutation (SNP) | VAF 116/281 reads (41%) | catalogued as COSV70479277; called by muse, mutect2, varscan2
- COL5A3 | c.2327G>C p.G776A | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53420623; called by muse, mutect2, varscan2
- CTSG | c.737A>T p.K246I | Missense Mutation (SNP) | VAF 185/757 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV53537155; called by muse, mutect2, varscan2
- CXCR3 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV65462403; called by muse, mutect2, varscan2
- DSCAM | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV68037994; called by muse, mutect2, varscan2
- EIF4G2 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV101150680; called by muse, mutect2
- ENTPD7 | c.324C>A p.N108K | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs764753437, COSV65113440; called by muse, mutect2, varscan2
- ERN2 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV55621449, COSV55624602; called by muse, mutect2, varscan2
- FAM171A1 | c.1222G>T p.G408W | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV65320802; called by muse, mutect2, varscan2
- GDAP2 | c.1446+1G>A p.X482_splice | Splice Site (SNP) | VAF 39/81 reads (48%) | catalogued as COSV65613529; called by muse, mutect2, varscan2
- IGSF1 | c.3943G>A p.G1315S | Missense Mutation (SNP) | VAF 17/649 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as rs1391402441, COSV100811979, COSV63840712; called by muse, mutect2
- IL16 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as COSV57260974; called by muse, mutect2, varscan2
- IMPA2 | c.770T>A p.M257K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99302477; called by muse, mutect2, varscan2
- ISLR | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs200106724; called by muse, mutect2, varscan2
- KPRP | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as rs763479865, COSV64223128; called by muse, mutect2, varscan2
- KRT2 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV59013055; called by muse, mutect2, varscan2
- KRTAP10-9 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 37/51 reads (73%) | catalogued as COSV59982577; called by muse, mutect2, varscan2
- LENG1 | c.313-1G>A p.X105_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as rs1171149475, COSV55369161; called by muse, mutect2, varscan2
- MAGI2 | c.1846G>C p.G616R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62703910; called by muse, mutect2, varscan2
- MAP3K7 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV65226310; called by muse, mutect2, varscan2
- MMRN1 | c.741G>C p.Q247H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99306804; called by muse, mutect2, varscan2
- MRPS22 | c.232C>G p.L78V (on ENST00000310776 / NM_001363893.1; = p.L79V on NM_020191.4) | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765088399, COSV60351489; called by muse, mutect2, varscan2
- MYO16 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748224248, COSV51798128, COSV51799233; called by muse, mutect2, varscan2
- NFKBIZ | c.1655-1G>T p.X552_splice | Splice Site (SNP) | VAF 32/80 reads (40%) | catalogued as COSV58202234; called by muse, mutect2, varscan2
- NLRP3 | c.2663+1G>C p.X888_splice | Splice Site (SNP) | VAF 90/226 reads (40%) | catalogued as COSV60232137; called by muse, mutect2, varscan2
- PDYN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 123/338 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370283678, COSV54101461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPH1 | c.1198G>A p.E400K (on ENST00000319170 / NM_213589.3; = p.E452K on NM_203365.4) | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57358548; called by muse, mutect2, varscan2
- RTL9 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 292/743 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs769855043, COSV71826581; called by muse, mutect2, varscan2
- SLC22A12 | c.121_143del p.S41Lfs*22 | Frame Shift Del (DEL) | VAF 14/20 reads (70%) | catalogued as COSV60574444; called by mutect2, varscan2
- SLC22A15 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65679198; called by muse, mutect2, varscan2
- SLC6A14 | c.323G>C p.W108S | Missense Mutation (SNP) | VAF 149/373 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64148952; called by muse, mutect2, varscan2
- SV2B | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV57702892; called by muse, mutect2, varscan2
- TAF1 | c.5139A>C p.E1713D (on ENST00000373790 / NM_138923.4; = p.E1734D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.931); catalogued as rs202061337, COSV52126119; called by muse, mutect2, varscan2
- TRIM24 | c.3006G>C p.K1002N (on ENST00000343526 / NM_015905.3; = p.K968N on NM_003852.4) | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.614); catalogued as COSV58979115; called by muse, mutect2, varscan2
- UNC13C | c.840T>A p.S280R | Missense Mutation (SNP) | VAF 99/141 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1381509767, COSV52931366; called by muse, mutect2, varscan2
- WDR5B | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV51660032; called by muse, mutect2, varscan2
- WNT16 | c.983G>A p.G328D (on ENST00000222462 / NM_057168.2; = p.G318D on NM_016087.2) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55978031; called by muse, mutect2, varscan2
- XIAP | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.494); catalogued as COSV63024208; called by muse, mutect2, varscan2
- ZNF81 | c.790A>G p.N264D | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV58578913; called by muse, mutect2, varscan2
- NEXMIF | c.3845_3881del p.D1282Vfs*3 | Frame Shift Del (DEL) | VAF 116/278 reads (42%) | called by mutect2, pindel
- VPS13C | c.5175_5210del p.K1726_A1737del (on ENST00000644861 / NM_020821.3; = p.K1683_A1694del on NM_017684.5) | In Frame Del (DEL) | VAF 31/46 reads (67%) | called by mutect2, pindel
- ALDH1A1 | c.903G>A p.Q301= | Silent (SNP) | VAF 126/287 reads (44%) | catalogued as rs1195979495, COSV52794952; called by muse, mutect2, varscan2
- CASP10 | c.756C>T p.V252= | Silent (SNP) | VAF 81/154 reads (53%) | catalogued as COSV53781008; called by muse, mutect2, varscan2
- CSRNP1 | c.672G>A p.K224= | Silent (SNP) | VAF 84/156 reads (54%) | catalogued as rs1411806302, COSV56190173; called by muse, mutect2, varscan2
- FLG | c.8025T>C p.A2675= | Silent (SNP) | VAF 47/293 reads (16%) | catalogued as COSV64251259; called by muse, mutect2, varscan2
- HADHB | c.306C>T p.I102= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV58549171; called by muse, mutect2, varscan2
- HORMAD1 | c.471T>A p.I157= | Silent (SNP) | VAF 46/170 reads (27%) | catalogued as COSV59273529; called by muse, mutect2, varscan2
- KIDINS220 | c.1983C>A p.V661= | Silent (SNP) | VAF 87/417 reads (21%) | catalogued as COSV56753428, COSV56760231; called by muse, mutect2, varscan2
- MMP2 | c.1647G>A p.E549= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV54606015; called by muse, mutect2, varscan2
- RFXANK | c.690C>T p.A230= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs751945050, COSV57395270; called by muse, mutect2, varscan2
- RTP3 | c.99T>A p.L33= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV56124583; called by muse, mutect2, varscan2
- SLC17A7 | c.531C>T p.I177= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV55550508; called by muse, mutect2, varscan2
- STAG3 | c.1956C>T p.L652= | Silent (SNP) | VAF 53/106 reads (50%) | catalogued as rs748821805, COSV57935767; called by muse, mutect2, varscan2
- TMBIM4 | c.234C>T p.L78= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs201499761; called by muse, mutect2, varscan2
- TRBV5-1 | c.72T>C p.T24= | Silent (SNP) | VAF 51/202 reads (25%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.210G>T | RNA (SNP) | VAF 36/90 reads (40%) | catalogued as COSV55601676; called by muse, mutect2, varscan2
